Somatic mutation profile of tumor specimen MP2PRT-PAVDHB-TMP1-A (aliquot MP2PRT-PAVDHB-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVDHB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,538 days).
Specimen MP2PRT-PAVDHB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52666ba2-76ad-4d94-af6b-dee83d2be76c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDHB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDHB-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d749e9e2-ec5c-4e50-ae25-ac47f54af277

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 27/368 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- ASB18 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1015310630; called by muse, mutect2, varscan2
- CYP4F22 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs779206543; called by muse, mutect2
- FAM171B | c.1638C>A p.D546E | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.07); catalogued as rs764737258; called by muse, mutect2, varscan2
- GYPE | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100679126, COSV62261477, COSV62261836; called by muse, mutect2
- KCNK13 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 108/615 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs144597895; called by muse, mutect2, varscan2
- LCN1 | c.504C>T p.S168= | Splice Region (SNP) | VAF 54/250 reads (22%) | catalogued as rs750192268, COSV99704514; called by muse, varscan2
- MGST1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370060966; called by muse, mutect2, varscan2
- POPDC3 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54646484; called by muse, mutect2, varscan2
- SLC1A2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 52/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771969810, COSV53527569; called by muse, mutect2, varscan2
- SLCO3A1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 62/784 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as COSV59233804; called by muse, mutect2
- TXNRD1 | c.1429C>T p.P477S (on ENST00000525566 / NM_001093771.3; = p.P379S on NM_003330.4) | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.267); catalogued as rs1451315965; called by muse, mutect2, varscan2
- DOT1L | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 94/436 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SF3A2 | c.1307A>G p.H436R | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.634); called by mutect2, varscan2
- TTN | c.39641T>A p.F13214Y (on ENST00000591111; = p.F5790Y on NM_003319.4) | Missense Mutation (SNP) | VAF 19/270 reads (7%) | PolyPhen possibly damaging (0.6); called by muse, mutect2
- TXNRD3 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ADAM33 | c.564G>A p.A188= | Silent (SNP) | VAF 103/376 reads (27%) | catalogued as rs367645851; called by muse, mutect2
- LCA5L | c.336A>C p.I112= | Silent (SNP) | VAF 37/297 reads (12%) | catalogued as COSV55746883; called by muse, mutect2, varscan2
- MAP3K15 | c.711G>T p.V237= | Silent (SNP) | VAF 52/149 reads (35%) | called by muse, mutect2, varscan2
- MYH6 | c.3594C>T p.H1198= | Silent (SNP) | VAF 67/571 reads (12%) | catalogued as rs768560994; called by muse, mutect2, varscan2
- RXFP3 | c.549G>A p.S183= | Silent (SNP) | VAF 36/798 reads (5%) | called by muse, mutect2
- TSHZ3 | c.2994C>T p.H998= | Silent (SNP) | VAF 78/365 reads (21%) | called by muse, mutect2, varscan2
